Surgical pathology report (de-identified scan), TCGA case TCGA-B8-5162, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site UNC, specimen TCGA-B8-5162-01A (Primary Tumor).

[page 1 of 2]
Case Number : [REDACTED]

Surgical Pathology Report

Diagnosis:

Kidney, left, partial nephrectomy

Histologic tumor type/subtype: renal cell carcinoma, clear cell type

Histologic grade (if applicable): Fuhrman nuclear grade 2 (of 4)

Tumor size (greatest dimension): 7.3 cm

Extent of tumor invasion:

Capsular invasion/perirenal adipose tissue: negative for tumor

Gerota's fascia: negative for tumor

Renal vein: N/A

Ureter: segment of ureter, negative for tumor

Venous (large vessel): negative for tumor

Lymphatic (small vessel): negative for tumor

Histologic assessment of surgical margins:

Perirenal adipose tissue: negative for tumor

Gerota's fascia: negative for tumor

Renal vein: N/A

Renal artery: N/A

Ureter: negative for tumor

Adrenal gland: not present

Lymph nodes: none identified

Other significant findings:

- Segment of ureter with no significant pathologic abnormality, negative for malignancy
- Non-neoplastic kidney with mild to moderate arterionephrosclerosis

AJCC Staging:

pT2a pNx

This staging information is based on information available at the time of this report, and is subject to change pending clinical review and additional information.

Clinical History:

with a renal mass.

Gross Description:

Specimen fixation: Formalin

Type of specimen: Partial nephrectomy

Side of specimen: Left

Size and weight of specimen: 252.3 grams, 14 x 10 x 7 cm composed of a 9 x 7 x 7 cm heminephrectomy. No hilar structures are identified with the exception of a 9 mm long x 6 mm in diameter segment of intact ureter, loosely attached.

[page 2 of 2]
The specimen consists of the anterior one-half of the left kidney.

Orientation: The perinephric fat is marked with black ink, the parenchymal margin is marked with blue ink and the ureter is marked with green ink.

Presence/absence of adrenal gland: Absent

Tumor description/site: The tumor is a solid, variegated red/tan/orange mass with a thick capsule located in the anterior portion of the specimen and focally expands the anterior capsule.

Tumor size: 7.3 x 6.2 x 5.5 cm

Presence/absence of multicentricity: Absent

Confinement/non-confinement to the kidney: Appears confined to the kidney.

Extent of invasion:

Perirenal adipose tissue: Tumor grossly does not involve

Gerota's fascia: Tumor grossly does not involve

Renal vein: N/A

Ureter: Tumor grossly does not involve

Other organs: N/A

Surgical margins:

Perirenal adipose tissue: Within 0.1 cm, but grossly negative

Renal vein: N/A

Renal artery: N/A

Ureter: N/A

Parenchymal margin: The tumor is 1.2 cm from the closest blue-inked parenchymal margin

Description of kidney away from tumor: The renal parenchyma towards the parenchymal margin is gray/tan and grossly unremarkable.

Lymph nodes (hilar): N/A

Other significant findings: None

Tissue submitted for special investigations: Tumor is given to tissue procurement.

Digital photograph taken: No

Block Summary:

Inking: Perinephric fat/black, parenchymal margin/blue, segment of ureter/green

A1 - Ends of ureter segment

A2 - Tumor expanding renal capsule

A3 - Tumor and black inked perinephric fat

A4 - Tumor and blue inked parenchymal margin

A5 - Tumor and renal parenchyma

A6 - Central tumor

A7 - Additional section of tumor and black inked perinephric margin

A8 - Normal kidney, superior pole

Light Microscopy:

Light microscopic examination is performed.

Signature

Attending Pathologist: I have personally conducted the evaluation of the above specimens and have rendered the above diagnosis(es).

Source: NCI Genomic Data Commons file 82bc81e2-190d-44f2-b39d-d30fa995f134 (TCGA-B8-5162.91654C64-FF5C-42D3-A5F1-76894B38FF20.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).